National Lung Screening Trial (NLST) participant 205077 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 56 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 5): Negative screen, no significant abnormalities.
- T1 (day 342): Negative screen, no significant abnormalities.
- T2 (day 712): Negative screen, no significant abnormalities.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T3; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,242, study year T3. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: right hilum, right main stem bronchus, mediastinum. Histology: small cell carcinoma, NOS (ICD-O-3 8041/3). Grade: undifferentiated (G4). Tumour size on pathology: 100 mm. AJCC 6th edition staging: stage IV (best stage, from pathologic TNM); clinical T4 NX M1 (stage IV); pathologic T4 N0 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical T4 N1 M1b; pathologic TX NX MX. Summary stage: distant. VALCSG stage (the small-cell staging system; ACRIN recorded it for all its lung cancers): extensive.

Follow-up
Last known free of lung cancer: day 1,242 (for ACRIN participants with lung cancer this field holds the diagnosis date).
